Surgical pathology report (de-identified scan), TCGA case TCGA-85-8664, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8664-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED] Case ID	[REDACTED] ID	Excision date
[REDACTED]	[REDACTED]	[REDACTED]

[page 2 of 3]
Gross Description	Microscopic Description	Diagnosis Details
Lung tissue of 18 x 19 cm with the tumour of 7 cm in size, grey-pinkish coloured, with necrosis.	Squamous carcinoma, G2, with necrosis. Seven bronchopulmonary lymph nodes were examined, one demonstrated metastases. One tracheobronchial lymph node-antracosis.	Tumor Features: Unknown, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 3 of 3]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Pneumonectomy Tumor site: Lung Tumor size: 0 x 0 x 7 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 1/8 positive for metastasis (Bronchopulmonary, tracheobronchial, aortic window 1/8) Lymphatic invasion: Not specified Venous invasion: Absent Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Right- upper

Source: NCI Genomic Data Commons file 3259fb26-884c-4def-b7da-a32bac955fd9 (TCGA-85-8664.CD29DCF4-5B1A-4288-9113-182BC79AE361.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).